Gene-level copy-number profile of tumor specimen TCGA-F7-A623-01A from TCGA case TCGA-F7-A623, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 70.1 years (25,592 days).
Specimen TCGA-F7-A623-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.73810065-978f-4d2b-9906-527ff956992e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F7-A623-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9d70a09-3f62-41c2-9bd2-f8dbf5acdf0e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 77; copy number 2: 9,994; copy number 3: 16,420; copy number 4: 18,294; copy number 5: 7,650; copy number 6: 2,830; copy number 7: 1,769; copy number 8: 436; copy number 9: 1,793; copy number 10: 110; copy number 11: 106; copy number 13: 3; copy number 14: 67; copy number 15: 7; copy number 20: 104; copy number 26: 19; copy number 34: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-A623-01A-11D-A28Q-01): tumor purity 0.41, ploidy 4.02, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 1 gene (within-gene range 0–2): FHIT.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr7:141,551,278–141,787,922, 9 genes (within-gene range 0–2): AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,303 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–10,016,021, 341 genes, copy number 9 (broad region; genes not listed).
- chr1:10,054,445–10,059,648, 2 genes, copy number 9: AL590639.1, PGAM1P11.
- chr1:229,508,369–229,558,707, 3 genes, copy number 13 (within-gene range 4–13): AL121990.1, ABCB10, RNU4-21P.
- chr2:200,305,881–202,205,188, 74 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr3:93,843,764–100,577,444, 96 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr3:106,449,775–119,807,570, 208 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr6:51,599,723–54,485,850, 72 genes, copy number 9–14 (broad region; genes not listed).
- chr6:70,216,040–70,303,084, 1 gene, copy number 11 (within-gene range 3–11): COL9A1.
- chr6:70,345,919–70,862,011, 12 genes, copy number 11 (within-gene range 5–11): AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1.
- chr6:71,886,703–73,329,017, 20 genes, copy number 10 (within-gene range 5–10): RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3.
- chr6:87,407,972–91,739,897, 69 genes, copy number 9–10 (within-gene range 5–10) (broad region; genes not listed).
- chr8:59,119,040–74,029,079, 228 genes, copy number 14–34 (broad region; genes not listed).
- chr8:101,686,542–102,124,907, 1 gene, copy number 9 (within-gene range 8–9): NCALD.
- chr8:101,847,256–145,066,685, 653 genes, copy number 9 (broad region; genes not listed).
- chr9:95,085,208–95,086,094, 4 genes, copy number 15: MIR23B, MIR27B, MIR3074, MIR24-1.
- chr9:95,113,708–95,142,541, 3 genes, copy number 15: AL354893.2, AL354893.1, RNA5SP288.
- chr12:25,409,307–25,648,579, 1 gene, copy number 11 (within-gene range 6–11): LMNTD1.
- chr12:25,435,581–26,335,856, 18 genes, copy number 11 (within-gene range 8–11): FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4.
- chr12:27,243,968–27,972,733, 25 genes, copy number 10: STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2.
- chr12:28,163,298–28,319,463, 5 genes, copy number 10: AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P.
- chr19:29,287,011–30,713,538, 25 genes, copy number 9 (within-gene range 5–9): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr19:32,581,190–36,772,825, 210 genes, copy number 9 (broad region; genes not listed).
- chr19:37,401,404–41,730,433, 232 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
